Somatic mutation profile of cancer-model specimen HCM-CSHL-0462-D05-85T (3D Organoid, passage 3; aliquot HCM-CSHL-0462-D05-85T-01D-A83U-36), derived from the primary tumor of HCMI case HCM-CSHL-0462-D05, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Intraductal carcinoma, noninfiltrating, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 49.1 years (17,939 days).
Specimen HCM-CSHL-0462-D05-85T: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5e604b9-a36e-4b15-a19d-98ef0f2109da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0462-D05-10A (Blood Derived Normal), aliquot HCM-CSHL-0462-D05-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9e3b127-2c80-4594-a5fa-baac776cc692

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Splice Region 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 195/570 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KDM6B | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.527); catalogued as rs373942826; called by muse, mutect2
- KNDC1 | c.303C>T p.D101= | Splice Region (SNP) | VAF 100/361 reads (28%) | catalogued as rs770540856, COSV100464610; called by muse, mutect2, varscan2
- PIGO | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs755660562; called by muse, mutect2
- PKP2 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 46/702 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763433296; called by muse, mutect2
- RARRES1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 299/868 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1335366665, COSV52961577; called by muse, mutect2, varscan2
- RXFP1 | c.1543G>T p.V515F | Missense Mutation (SNP) | VAF 14/467 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs932192036; called by muse, mutect2
- SH3PXD2A | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 54/790 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs578015462; called by muse, mutect2
- STAU1 | c.944G>A p.R315H (on ENST00000371856 / NM_001319135.1; = p.R234H on NM_004602.3) | Missense Mutation (SNP) | VAF 36/435 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907527599; called by muse, mutect2
- TSG101 | c.846C>T p.A282= | Splice Region (SNP) | VAF 37/182 reads (20%) | catalogued as rs369798357; called by muse, mutect2, varscan2
- ADGRA2 | c.3566G>A p.G1189E | Missense Mutation (SNP) | VAF 65/1105 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2
- EFCAB5 | c.2771C>A p.P924H | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2
- ESRP1 | c.82_84del p.K28del | In Frame Del (DEL) | VAF 49/425 reads (12%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.4210G>A p.E1404K | Missense Mutation (SNP) | VAF 110/369 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MBD6 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 109/395 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- OSBP2 | c.2124G>T p.K708N | Missense Mutation (SNP) | VAF 108/387 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by mutect2, varscan2
- STRADA | c.125C>G p.T42S (on ENST00000336174 / NM_001363786.1; = p.T5S on NM_153335.6) | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- TTN | c.86465A>C p.Q28822P (on ENST00000591111; = p.Q21398P on NM_003319.4) | Missense Mutation (SNP) | VAF 28/474 reads (6%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- ZFPM1 | c.501del p.K168Rfs*19 | Frame Shift Del (DEL) | VAF 29/291 reads (10%) | called by mutect2, pindel
- ADGRA2 | c.3567A>T p.G1189= | Silent (SNP) | VAF 65/1104 reads (6%) | called by muse, mutect2
- ALPK3 | c.4917C>T p.G1639= | Silent (SNP) | VAF 68/700 reads (10%) | catalogued as rs1193979581; called by muse, mutect2
- NRG3 | c.1644C>A p.P548= (on ENST00000404547 / NM_001370084.1; = p.P327= on NM_001165973.1) | Silent (SNP) | VAF 75/283 reads (27%) | called by muse, mutect2, varscan2
- PHYHIP | c.702C>T p.Y234= | Silent (SNP) | VAF 52/684 reads (8%) | catalogued as rs372640612; called by muse, mutect2
- RIMBP2 | c.2583G>A p.P861= | Silent (SNP) | VAF 88/480 reads (18%) | catalogued as rs143479429, COSV55472669; called by muse, mutect2, varscan2
- TBC1D9 | c.1710A>G p.E570= | Silent (SNP) | VAF 123/391 reads (31%) | catalogued as rs1233274772; called by muse, mutect2, varscan2
